Somatic mutation profile of tumor specimen ALCH-B73A-TTP1-A (aliquot ALCH-B73A-TTP1-A-1-0-D-A95Q-47) from ALCHEMIST case ALCH-B73A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,286 days).
Specimen ALCH-B73A-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc6d7011-861e-4d50-88bc-07ce929b8a51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B73A-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B73A-NB1-A-1-0-D-A95Q-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1396ca7-1133-455e-9ff2-986349c48265

The open-access MAF lists 107 somatic variants for this specimen: 75 protein-altering or splice-affecting, 25 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 25, Intron 4, Nonsense Mutation 3, RNA 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 18/208 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 11/131 reads (8%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2
- ACTL7B | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101012488; called by muse, mutect2
- C11orf1 | c.18T>G p.C6W | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV52791061; called by muse, mutect2, varscan2
- CHD1 | c.1102C>G p.P368A | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV52337566; called by muse, mutect2
- DDX46 | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62801368; called by muse, mutect2
- DNASE1L3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1420216657, COSV100568625; called by muse, mutect2, varscan2
- DNHD1 | c.5081G>C p.R1694T | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1389956596; called by muse, mutect2
- GLE1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as rs780599277; called by muse, mutect2, varscan2
- GNL3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs199658349; called by muse, mutect2
- HDAC9 | c.1748G>C p.R583P | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV67766236; called by muse, mutect2, varscan2
- IQCH | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs757368706, COSV60055304; called by muse, mutect2
- MCRIP2 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs1221474428; called by muse, mutect2, varscan2
- MUC5B | c.8480C>T p.T2827M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs372437958; called by muse, mutect2
- NAA35 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100863284; called by muse, mutect2
- PASD1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761622222, COSV64854816; called by muse, mutect2, varscan2
- PDE3B | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as rs1196678220; called by muse, mutect2, varscan2
- PDE8A | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1222654083; called by muse, varscan2
- PRELID3B | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1387674730; called by muse, mutect2
- SIK2 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.269); catalogued as rs778917625; called by muse, mutect2, varscan2
- SUPT6H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs897919382, COSV58924533; called by muse, mutect2
- TICRR | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs773729254; called by muse, mutect2, varscan2
- TTN | c.62493G>A p.W20831* (on ENST00000591111; = p.W13407* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 29/322 reads (9%) | catalogued as COSV59876718; called by muse, mutect2
- USP29 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as rs1265823109; called by muse, mutect2
- VDAC3 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV99195127; called by muse, mutect2
- ZNF30 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs374989332; called by muse, mutect2
- ZPLD1 | c.472C>G p.P158A (on ENST00000466937 / NM_001329788.1; = p.P174A on NM_175056.2) | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100082972, COSV60355053; called by muse, mutect2, varscan2
- AHNAK2 | c.7327G>A p.E2443K | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ANKLE2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.057); called by muse, mutect2
- CARD6 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CBFA2T2 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- CNOT11 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.398); called by muse, mutect2
- COL17A1 | c.3312G>C p.L1104F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.522); called by muse, mutect2
- COL18A1 | c.4384C>T p.P1462S (on ENST00000359759 / NM_130444.3; = p.P1227S on NM_030582.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ10B | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CPD | c.1119G>C p.L373F | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCLK3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2
- DENND4C | c.5075G>T p.G1692V (on ENST00000434457 / NM_001330640.2; = p.G1643V on NM_017925.7) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK11 | c.3435G>C p.L1145F | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- EEF1AKMT1 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIPC1 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR5A | c.5042G>T p.G1681V | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- HELZ | c.4270C>G p.Q1424E | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); called by muse, mutect2
- HELZ | c.4030C>G p.L1344V | Missense Mutation (SNP) | VAF 27/275 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); called by muse, mutect2
- KIAA1210 | c.4167del p.F1389Lfs*10 | Frame Shift Del (DEL) | VAF 36/192 reads (19%) | called by mutect2, pindel, varscan2
- LEMD3 | c.2464C>T p.H822Y | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- LRRC42 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- MARCO | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAST3 | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- MMP9 | c.86T>A p.V29E | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- NCOA2 | c.2597C>G p.S866* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- NRDC | c.2999G>C p.R1000T | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, varscan2
- OR2V1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PAN2 | c.3057T>A p.N1019K (on ENST00000425394 / NM_001127460.3; = p.N1015K on NM_014871.5) | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PDE4B | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIBF1 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- POLQ | c.2283G>A p.M761I | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- PPP2R1A | c.1446C>G p.I482M | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- PRB2 | c.1129C>G p.P377A | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); called by muse, mutect2
- PRDM8 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.293); called by muse, varscan2
- RCN2 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- RGPD4 | c.5263C>G p.Q1755E | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- RPN2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- SH3D19 | c.2147G>C p.R716T | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SPIDR | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPOPL | c.1011A>C p.K337N | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); called by muse, mutect2
- ST3GAL3 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- STX19 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- STYXL2 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SYDE2 | c.2523A>C p.E841D | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TPX2 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSGA10 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); called by muse, mutect2
- VWA8 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ZFYVE1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ZNF804B | c.3421C>T p.P1141S | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AC005833.1 | c.1272C>T p.I424= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as rs780520873, COSV52894203; called by muse, mutect2
- AHNAK | c.2481G>A p.L827= | Silent (SNP) | VAF 25/228 reads (11%) | catalogued as COSV99945342; called by muse, mutect2, varscan2
- C9orf131 | c.864G>A p.L288= | Silent (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- CCDC88B | c.4422C>T p.L1474= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- FREM3 | c.1041G>C p.L347= | Silent (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- GID8 | c.364C>T p.L122= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs1387470499; called by muse, mutect2, varscan2
- HSPA2 | c.288G>C p.V96= | Silent (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- JMJD1C | c.6669G>A p.L2223= | Silent (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- LAG3 | c.678C>G p.L226= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1428C>T p.L476= | Silent (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2, varscan2
- MAP3K7 | c.1329G>A p.L443= (on ENST00000369329 / NM_145331.3; = p.L416= on NM_003188.4) | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs1221500929, COSV100997552; called by muse, mutect2, varscan2
- MED13 | c.1605A>T p.P535= | Silent (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- MMP19 | c.36C>A p.L12= | Silent (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- OBSCN | c.22545C>G p.L7515= | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- OR2T11 | c.546G>A p.L182= | Silent (SNP) | VAF 13/358 reads (4%) | catalogued as COSV58184982; called by muse, mutect2
- OR2T4 | c.927C>T p.F309= | Silent (SNP) | VAF 38/627 reads (6%) | called by muse, mutect2
- PCDHB5 | c.2250C>T p.Y750= | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as rs374460300, COSV50676756; called by muse, mutect2
- PRICKLE1 | c.396G>A p.K132= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- SETDB1 | c.3627C>T p.I1209= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- SLC4A4 | c.2841G>T p.L947= (on ENST00000264485 / NM_001098484.3; = p.L903= on NM_003759.4) | Silent (SNP) | VAF 55/266 reads (21%) | called by muse, mutect2, varscan2
- SPPL2A | c.876C>G p.L292= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- SSTR3 | c.798C>T p.F266= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs750163700; called by muse, mutect2, varscan2
- TESMIN | c.816C>G p.L272= | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- URI1 | c.858G>A p.L286= | Silent (SNP) | VAF 22/350 reads (6%) | called by muse, mutect2
- ZBTB4 | c.2682G>A p.G894= | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- AC241952.1 | n.4400A>G | RNA (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- AMT | c.*180C>G | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- DEFB108F | n.3G>A | RNA (SNP) | VAF 22/313 reads (7%) | called by muse, mutect2
- NCSTN | c.86-118C>G | Intron (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- RBM44 | c.-98-3143C>A | Intron (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- SPATA13 | c.-222-24903_-222-24901del | Intron (DEL) | VAF 5/47 reads (11%) | catalogued as rs1378263594; called by mutect2, pindel
- SYTL2 | c.1459+2055C>T | Intron (SNP) | VAF 20/413 reads (5%) | called by muse, mutect2
